Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A3G9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A3G9-01A (Primary Tumor).

[page 1 of 4]
HPA Discrepancy		☒

*** FINAL REPORT ***

Provider:

Pt. Name:

Acc #:

Pt. MRN:

Col Date:

DOB/Sex:

Rec Date:

LOC:

105-0-3

SURGICAL PATHOLOGY

adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium c54.1
11/29/11

---Pathologic Diagnosis---

A - Uterus, bilateral fallopian tubes and ovaries, resection:

Specimen type: Hysterectomy and bilateral salpingo-oophorectomy
Histologic type: Endometrial carcinoma, endometrioid type with foci of squamous differentiation

FIGO grade: III

Architectural grade: 3

Nuclear grade: 2-3

Tumor size: 2.3 cm in diameter

Myometrial invasion

(no invasion, <1/2, >1/2): < 1/2

Depth of invasion (mm) 8.0 mm

Width of myometrium (mm) 18.0 mm

Myometrial lymphovascular

space invasion: Present

Lower uterine segment

involvement: Absent

Cervical involvement: Cervix free of tumor

Other: 1. Adenomyosis

2. Bilateral fallopian tubes and ovaries, no evidence of malignancy

B - Right pelvic lymph nodes, excision:

Two lymph nodes, no evidence of malignancy (0/2).

C - Right para-aortic lymph node, excision:

One lymph node, no evidence of malignancy (0/1).

D - Left pelvic lymph node, excision:

One lymph node, no evidence of malignancy (0/1).

E - Left pelvic lymph node, excision:

Metastatic carcinoma in one lymph node (1/1).

Pathologic Stage: pT1a pN1[IIIC1]pMX

[page 2 of 4]
Verified by:

Pathologist
(Electronic Signature)

The attending pathologist whose signature appears on this report has reviewed all diagnostic slides and has edited the gross and/or microscopic portion of the report in rendering the final pathologic diagnosis.

---Frozen Section Diagnosis---

Frozen section(s) performed. Please refer to separate electronic frozen section report(s).

---Microscopic Description---

Slides reviewed, microscopic description not recorded.

---Gross Description---

A - Labeled/Fixative:	Uterus, cervix, bilateral tubes and ovaries; fresh.
Qty/Size/Weight:	12.0 x 7.0 x 5.0 cm, 79 g.
Tissue Description:	
Endometrial tumor	
Greatest dimension:	2.3 x 2.0 x 2.0 cm.
Qualitative description:	An exophytic mass with a well-circumscribed, pushing border.
Location:	Left side of the uterine cavity.
Myometrial invasion	
(<1/2 or >1/2):	Grossly less than one half.
Cervical involvement:	Negative grossly.
Gross lymphatic or	
vascular invasion:	Negative grossly
Endometrium:	The remaining endometrium is yellow, soft, with an average thickness of 0.2 cm. No separate tumor nodules are noted.
Myometrium:	Pink, soft, with numerous trabeculations.
Lesions:	No lesions are seen in the myometrium.
Thickness:	1.2 cm.
Uterine serosa:	Smooth, tan-pink with no evidence of nodularity.
Cervix:	Pink, soft. The os is patent. No lesions
	are noted in the cervix or endocervical canal.
Ovaries and fallopian tubes	
Right ovary	
Dimensions:	2.5 x 1.5 x 1.0 cm.
Outer surface:	Yellow and smooth.
Cut surface:	Unremarkable.
Right tube:	4.0 x 0.3 cm. The tube appears to have
been	crushed and electrocauterized. Small lumen is possibly visible.
Left ovary:	

[page 3 of 4]
Dimensions: 4.0 x 1.7 x 1.0 cm.
Outer surface: Yellow and smooth.
Cut surface: Unremarkable.
Left tube: 5.0 x 0.3 cm in diameter and shows a focal area of electrocautery charring and fibrosis, consistent with earlier tubal ligation.
Sections/Processing: Representative sections are submitted as follows: (1) anterior cervix; (2) posterior cervix; (3-5) anterior lower uterine segment, black marks superior margin; (6-9) posterior uterine segment, black marks superior margin; (10-11) tumor on anterior wall; (12-13) tumor on posterior wall; (14) right ovary; (15) right tube; (16) left ovary; (17) left tube. (R17) [REDACTED]

B - Labeled/Fixative: Right pelvic lymph nodes, fresh.
Qty/Size/Weight: Single, 3.0 x 3.0 x 1.5 cm.
Tissue Description: Mass of fibroadipose tissue within which two lymph nodes, ranging from 1.2 cm to 2.5 cm, are found. The lymph nodes are yellow, firm, with focal areas of hyperemia and hemorrhage.
Sections/Processing: The lymph nodes are serially sectioned along their longest axis and submitted as follows: (1-4) one lymph node, serially sectioned; (5-6) one lymph node, serially sectioned. (R6)

C - Labeled/Fixative: Right para-aortic lymph node, fresh.
Qty/Size/Weight: Single, 1.5 x 1.2 x 0.7 cm.
Tissue Description: This is a pad of fibroadipose tissue within which one lymph node is identified.

Sections/Processing: (T2)

D - Labeled/Fixative: Left pelvic lymph node, fresh.
Qty/Size/Weight: Single, 1.5 x 0.5 x 0.5 cm.
Tissue Description: This is a tan-pink lymph node surrounded by a small amount of fat.
Sections/Processing: Bisected and submitted for frozen section. (T1)

E - Labeled/Fixative: Left pelvic lymph nodes, fresh.
Qty/Size/Weight: Single lymph node, 4.0 x 1.0 x 1.0 cm.
Tissue Description: Elongated, firm, pink lymph node with surrounding fibroadipose tissue. The specimen is serially sectioned.
Sections/Processing: (T5) [REDACTED]

---Clinical Information---

Specimen Submitted:

A - Uterus, Cervix, Bilat. Tubes & Ovaries, Pelvis

B - Right Pelvic Lymph Nodes, Pelvis

[page 4 of 4]
- C - Right para-aortic Lymph Node, Pelvis
- D - Left Pelvic Lymph Node, Pelvis for frozen section
- E - Left Pelvic Lymph Nodes, Pelvis

Clinical History:

[REDACTED]

Clinical Diagnosis:
Endometrial cancer

Source: NCI Genomic Data Commons file 527595a1-5804-441a-96df-cdd9c5dd731f (TCGA-AX-A3G9.FADFF649-7518-4EFB-B96C-9390DD308DBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).